Gene-level copy-number profile of tumor specimen TCGA-VD-A8K9-01A from TCGA case TCGA-VD-A8K9, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.0 years (26,292 days).
Specimen TCGA-VD-A8K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.073a8f48-b7fe-46e9-ac89-5ebbbe315090.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-A8K9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-VD-A8K9-01A|TCGA-VD-A8K9-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e042fc8-07e6-46ed-9638-02b3185432d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,173; copy number 2: 53,240; copy number 3: 3,498; copy number 4: 34; copy number 5: 1,875.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-A8K9-01A-11D-A39V-01): tumor purity 0.99, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,875 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–48,795,513, 1,372 genes, copy number 5 (broad region; genes not listed).
- chr8:116,289,622–145,066,685, 503 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
